Somatic mutation profile of tumor specimen TARGET-10-PARDWM-09A (aliquot TARGET-10-PARDWM-09A-01D) from TARGET case TARGET-10-PARDWM, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.4 years (5,641 days).
Specimen TARGET-10-PARDWM-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 11bd4ab3-3828-4667-b812-75c1af53d707.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARDWM-10A (Blood Derived Normal), aliquot TARGET-10-PARDWM-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7a05f773-0253-4181-aeba-52063a22e586

The open-access MAF lists 16 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Intron 3, Silent 3, Frame Shift Ins 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CRLF2 | c.695T>G p.F232C | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as rs1057519743, COSV67493408; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARID5B | c.1514C>T p.A505V | Missense Mutation (SNP) | VAF 43/85 reads (51%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs149466999, COSV54424106; called by muse, mutect2, varscan2
- IKZF1 | c.472G>A p.G158S | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV58780577; called by muse, mutect2, varscan2
- CDKL3 | c.794C>T p.A265V | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); called by muse, mutect2
- HDAC6 | c.3128A>T p.Q1043L | Missense Mutation (SNP) | VAF 14/149 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2
- HES1 | c.288dup p.T97Dfs*36 | Frame Shift Ins (INS) | VAF 19/49 reads (39%) | called by mutect2, pindel, varscan2
- ITGB8 | c.1404C>A p.S468R | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- ZMAT1 | c.1761G>C p.K587N | Missense Mutation (SNP) | VAF 9/159 reads (6%) | SIFT tolerated (0.59); PolyPhen benign (0.038); called by muse, mutect2
- ZNF217 | c.312_313insGA p.L105Dfs*44 | Frame Shift Ins (INS) | VAF 50/169 reads (30%) | called by mutect2, pindel, varscan2
- CDH11 | c.39C>T p.C13= | Silent (SNP) | VAF 14/28 reads (50%) | catalogued as rs148395832; called by muse, mutect2, varscan2
- DNAH7 | c.4524T>A p.V1508= | Silent (SNP) | VAF 6/135 reads (4%) | catalogued as rs1285886881; called by muse, mutect2
- OR5F1 | c.288C>A p.G96= | Silent (SNP) | VAF 24/59 reads (41%) | catalogued as COSV53545145; called by muse, mutect2, varscan2
- ATP10A | c.449+392_449+393insCCC | Intron (INS) | VAF 31/81 reads (38%) | called by mutect2, pindel, varscan2
- GRIP2 | c.858-33C>T | Intron (SNP) | VAF 3/9 reads (33%) | catalogued as rs1181527271; called by muse, mutect2
- HDHD5 | chr22:17159407 G>A | 5'Flank (SNP) | VAF 3/36 reads (8%) | catalogued as rs971424458; called by muse, mutect2
- YY1AP1 | c.1134+161C>T | Intron (SNP) | VAF 7/17 reads (41%) | catalogued as rs574279553, COSV99803380; called by muse, mutect2, varscan2
